Somatic mutation profile of tumor specimen ALCH-B2FD-TTP1-A (aliquot ALCH-B2FD-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2FD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.8 years (18,541 days).
Specimen ALCH-B2FD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 116acbd0-b841-40e3-b042-83ec7a386096.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FD-NB1-A (Blood Derived Normal), aliquot ALCH-B2FD-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80d14a99-bb75-4d6f-a6f2-e7d7382d81da

The open-access MAF lists 373 somatic variants for this specimen: 269 protein-altering or splice-affecting, 55 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 55, Intron 25, Nonsense Mutation 24, 3'UTR 6, Splice Region 5, Splice Site 5, 5'UTR 5, RNA 5, 5'Flank 5, Frame Shift Del 4, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 52/205 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM014696, COSV58688961, COSV58702489, COSV58705912; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 53/253 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WAC | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 20/384 reads (5%) | catalogued as rs1057518233, COSV61567167; ClinVar: pathogenic; called by muse, mutect2
- ACP4 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as rs375408855, COSV99076182; called by muse, mutect2, varscan2
- ACTB | c.416T>G p.V139G | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV59316637; called by muse, mutect2
- ADAMTS15 | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs752169369; called by muse, mutect2
- ANKRD11 | c.606G>T p.W202C | Missense Mutation (SNP) | VAF 33/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56363410; called by muse, mutect2
- ANO5 | c.1067G>T p.C356F | Missense Mutation (SNP) | VAF 50/722 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM155159; called by muse, mutect2
- APC | c.119G>C p.S40T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs587778028; ClinVar: conflicting interpretations of pathogenicity / not provided; called by muse, mutect2
- APLP1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 24/154 reads (16%) | catalogued as COSV55706882; called by muse, mutect2, varscan2
- APOB | c.4967C>T p.A1656V | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs1165705991; called by muse, mutect2, varscan2
- APOE | c.701C>A p.A234E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.834); catalogued as CM043810; called by muse, mutect2
- ARHGAP23 | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418128722; called by muse, mutect2, varscan2
- ARHGAP28 | c.1424A>G p.Y475C (on ENST00000383472 / NM_001366230.1; = p.Y316C on NM_001010000.3) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51642722; called by muse, mutect2, varscan2
- ASIC5 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV73332749; called by muse, mutect2, varscan2
- ATXN2 | c.2990A>G p.Y997C (on ENST00000550104; = p.Y837C on NM_002973.4) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750803688; called by muse, mutect2, varscan2
- BLK | c.302T>A p.V101D | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.148); catalogued as rs779200388; called by muse, mutect2
- C11orf96 | c.1243G>A p.E415K (on ENST00000339446; = p.E102K on NM_001145033.2) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs761632392; called by muse, mutect2, varscan2
- C7orf33 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 22/279 reads (8%) | catalogued as COSV104406094; called by muse, mutect2
- CACNA1S | c.3569T>C p.V1190A | Missense Mutation (SNP) | VAF 87/535 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1405148658; called by muse, mutect2, varscan2
- CD163L1 | c.3205G>T p.D1069Y | Missense Mutation (SNP) | VAF 27/399 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749297464, COSV58022415; called by muse, mutect2
- CNOT1 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs765937674; called by muse, mutect2
- COL28A1 | c.3052G>C p.E1018Q | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV68081901; called by muse, mutect2, varscan2
- CYP4A22 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs772583047, COSV53739901; called by muse, mutect2
- DCAF4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750942030; called by muse, mutect2, varscan2
- DLL3 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs898346981; called by muse, mutect2
- DNAH9 | c.12643G>A p.A4215T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs975048147, COSV52350228; called by mutect2, varscan2
- FAM120A | c.2671G>A p.V891I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.062); catalogued as rs748224233; called by muse, varscan2
- FAM71C | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752986456, COSV60944096; called by muse, mutect2, varscan2
- FAT3 | c.12266G>T p.G4089V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756101488; called by muse, mutect2, varscan2
- FCGR3B | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs562294556, COSV54208861; called by muse, mutect2, varscan2
- FER1L6 | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.884); catalogued as rs1179563876; called by muse, mutect2, varscan2
- FMO1 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 25/282 reads (9%) | catalogued as COSV100707692, COSV100707694; called by muse, mutect2
- FN1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552465703, COSV60546579; called by muse, mutect2
- FYB2 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100599172; called by muse, mutect2, varscan2
- GEMIN5 | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53558111; called by muse, mutect2
- GIGYF2 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 11/299 reads (4%) | catalogued as COSV65245870; called by muse, mutect2
- GK5 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs777209248; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious, low confidence (0); catalogued as rs748824436; called by muse, mutect2
- GPNMB | c.1677G>T p.K559N (on ENST00000381990 / NM_001005340.2; = p.K547N on NM_002510.3) | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV51698005; called by muse, mutect2
- GPR22 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99772072; called by muse, mutect2
- HCN1 | c.2258C>A p.P753Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV57535525; called by muse, mutect2, varscan2
- HK2 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs749039453; called by muse, mutect2, varscan2
- IRF3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as rs772574723; called by muse, mutect2
- KCNA4 | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs199975003; called by muse, mutect2
- KCNU1 | c.1862G>T p.C621F | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99063913; called by muse, mutect2, varscan2
- KIAA0513 | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50741905, COSV50742499; called by muse, mutect2
- KRT6A | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 37/431 reads (9%) | catalogued as COSV100417318; called by muse, mutect2, varscan2
- LAMC2 | c.1286-1G>A p.X429_splice | Splice Site (SNP) | VAF 36/423 reads (9%) | catalogued as COSV51459567; called by muse, mutect2
- LHX4 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1439530988; called by muse, mutect2, varscan2
- LRP1 | c.8330C>T p.S2777F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV54504283; called by muse, mutect2, varscan2
- MAGEC3 | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV53579633; called by muse, mutect2, varscan2
- MAP3K4 | c.1938G>C p.L646F | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100815060; called by muse, mutect2, varscan2
- NLRP2 | c.1992G>C p.E664D | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV99672598; called by muse, mutect2, varscan2
- NR3C1 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as COSV51545696; called by muse, mutect2, varscan2
- NTRK1 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 28/429 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV62328303; called by muse, mutect2
- NUFIP2 | c.957del p.G321Efs*32 | Frame Shift Del (DEL) | VAF 35/234 reads (15%) | catalogued as COSV56605928; called by mutect2, pindel, varscan2
- OPA1 | c.1541G>A p.G514E (on ENST00000361510 / NM_130837.3; = p.G459E on NM_015560.3) | Missense Mutation (SNP) | VAF 55/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM126969; called by muse, mutect2
- OR52I2 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754995723; called by muse, mutect2, varscan2
- OR9Q2 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 43/151 reads (28%) | catalogued as rs149505103, COSV61112628; called by muse, mutect2, varscan2
- PCLO | c.7888G>C p.E2630Q | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV100440335, COSV61633111; called by muse, mutect2
- PDE6A | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs775843654; called by muse, mutect2, varscan2
- PDHA2 | c.270C>A p.H90Q | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256830271; called by muse, mutect2, varscan2
- PKHD1 | c.12162C>A p.C4054* | Nonsense Mutation (SNP) | VAF 50/424 reads (12%) | catalogued as rs745888824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.4789G>A p.G1597S | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs1422530615, COSV61888255; called by muse, mutect2, varscan2
- PRKAB2 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1553913101; called by muse, mutect2, varscan2
- PSG6 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1010388966; called by muse, mutect2
- RAET1L | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 42/606 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.678); catalogued as rs1272054611, COSV53953900; called by muse, mutect2
- RASA2 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs762057353; called by muse, mutect2, varscan2
- RHCG | c.727G>T p.G243W | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51515029; called by muse, mutect2, varscan2
- SEMA3A | c.2241G>T p.W747C | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99545295; called by muse, mutect2
- SLC22A12 | c.1247C>A p.A416E | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60571739; called by muse, mutect2, varscan2
- SLC26A4 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 29/344 reads (8%) | catalogued as COSV55915800; called by muse, mutect2
- SLC7A13 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as rs539993555; called by muse, mutect2, varscan2
- SLC9A7 | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs774104509, COSV100091376; called by muse, mutect2, varscan2
- SNTG1 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV52457073; called by muse, mutect2, varscan2
- SORCS1 | c.2879G>T p.G960V | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99544687; called by muse, mutect2, varscan2
- SPHKAP | c.2519G>T p.G840V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60881657; called by muse, mutect2, varscan2
- SPNS1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100209263; called by muse, mutect2
- SRPK3 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.028); catalogued as rs782697914, COSV99473414; called by muse, mutect2, varscan2
- SYNE1 | c.2354T>A p.M785K (on ENST00000367255 / NM_182961.4; = p.M792K on NM_033071.3) | Missense Mutation (SNP) | VAF 103/461 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs761735368; called by muse, mutect2, varscan2
- SYNE1 | c.1306G>A p.E436K (on ENST00000367255 / NM_182961.4; = p.E443K on NM_033071.3) | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs373901808; called by muse, mutect2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 42/284 reads (15%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- TSBP1 | c.913C>A p.L305I (on ENST00000617061; = p.L308I on NM_006781.5) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.99); catalogued as COSV66660762; called by muse, mutect2, varscan2
- UGT8 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV60416153; called by muse, mutect2, varscan2
- VEPH1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV100747861; called by muse, mutect2
- VPS41 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs769057710; called by muse, mutect2, varscan2
- WDR72 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 77/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs987690495, COSV64741471; called by muse, mutect2, varscan2
- XYLT1 | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); catalogued as rs547620151; called by muse, mutect2, varscan2
- ZNF134 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs764590289, COSV68696678; called by muse, mutect2, varscan2
- ZNF208 | c.2263G>T p.G755C | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68110600; called by muse, mutect2, varscan2
- ZNF350 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV54710321; called by muse, mutect2
- ZNF583 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52402056; called by muse, mutect2
- ZNF80 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV100352188, COSV57360534; called by muse, mutect2, varscan2
- ZNF98 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 31/270 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs746418327, COSV63336173; called by muse, mutect2, varscan2
- ZNF99 | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101233994, COSV68056227; called by muse, mutect2, varscan2
- A1CF | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ABCA8 | c.3160G>T p.E1054* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- ABCB5 | c.872T>A p.L291H | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ABL2 | c.3458C>A p.S1153Y (on ENST00000502732 / NM_007314.4; = p.S1138Y on NM_005158.5) | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- ACER1 | c.410T>A p.L137Q | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADAMTS16 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ADCY9 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADPRM | c.458T>A p.V153E | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- AEBP1 | c.1981C>A p.R661S | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGBL4 | c.1267+6C>A | Splice Region (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- ALK | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AMY2B | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- AP3D1 | c.3365_3366+13del p.X1122_splice | Splice Site (DEL) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- ARID2 | c.1083del p.K361Nfs*3 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- ARID5B | c.1030T>G p.Y344D | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ASB8 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); called by muse, mutect2
- BLVRB | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BPTF | c.8748G>T p.Q2916H | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- BTBD16 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- CACNA1A | c.7279C>T p.P2427S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- CBX2 | c.850T>A p.C284S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC171 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CCDC39 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.325); called by muse, mutect2
- CFAP221 | c.1311+2T>A p.X437_splice | Splice Site (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2
- CFAP61 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.373); called by muse, mutect2
- CHRNA6 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2
- COL13A1 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- COL5A1 | c.3478G>T p.E1160* | Nonsense Mutation (SNP) | VAF 32/334 reads (10%) | called by muse, mutect2
- COLQ | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.204); called by muse, mutect2
- CPAMD8 | c.366G>C p.Q122H (on ENST00000651564; = p.Q75H on NM_015692.5) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2
- CPD | c.3133C>G p.Q1045E | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2
- CTPS1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAPK1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLL3 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- DLL3 | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH5 | c.13215C>A p.S4405R | Missense Mutation (SNP) | VAF 95/537 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DPP10 | c.1066T>G p.C356G | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EDRF1 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 45/466 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- EFCAB8 | c.2595G>T p.W865C | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- EGFLAM | c.1523C>G p.T508R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ENAM | c.1322dup p.P443Sfs*23 | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- EP300 | c.4810C>T p.P1604S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- EPB41L3 | c.2756C>G p.T919R | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- EPB41L5 | c.803+1G>A p.X268_splice | Splice Site (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- EPHB1 | c.1914G>C p.L638F | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERFE | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, varscan2
- ESF1 | c.1403G>T p.R468M | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- EVX1 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- EYS | c.1214G>T p.C405F | Missense Mutation (SNP) | VAF 60/389 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- F13B | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 94/595 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM107B | c.101A>G p.H34R (on ENST00000378458 / NM_001320737.1; = p.H209R on NM_031453.3) | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM20C | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FER1L6 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- FERMT1 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- GAL3ST4 | c.995C>G p.A332G | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GALK2 | c.1122G>T p.M374I | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- GASK1A | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- GIPC2 | c.714G>T p.M238I | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2
- GOLGA6L2 | c.1651G>C p.A551P | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2
- GOT1L1 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- GPR183 | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GTF2H1 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- HERC2P2 | n.2530-2A>C | Splice Site (SNP) | VAF 32/430 reads (7%) | called by muse, varscan2
- HEXD | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPR | c.1594A>T p.R532W | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HSD17B11 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- IRF8 | c.1199A>T p.D400V | Missense Mutation (SNP) | VAF 36/395 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ITGA7 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH5 | c.298A>T p.M100L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ITPK1 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ITPRID1 | c.2480C>G p.S827* | Nonsense Mutation (SNP) | VAF 35/235 reads (15%) | called by muse, mutect2, varscan2
- KCNA10 | c.1190A>C p.E397A | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2D | c.13279G>T p.G4427* | Nonsense Mutation (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- KNDC1 | c.1067A>T p.Q356L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LPAR2 | c.841del p.L281Yfs*66 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- LRFN5 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRRC34 | c.871T>A p.Y291N (on ENST00000446859 / NM_001172779.2; = p.Y259N on NM_153353.5) | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- LTBP4 | c.2501A>T p.D834V (on ENST00000308370 / NM_001042544.1; = p.D797V on NM_003573.2) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MCCC1 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 53/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MDC1 | c.1348_1352del p.E450Rfs*3 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- MEGF10 | c.1691C>A p.S564* | Nonsense Mutation (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- MGAT5 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 40/412 reads (10%) | called by muse, mutect2
- MMP16 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- MUC16 | c.39606G>C p.L13202= | Splice Region (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- MXRA5 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYL5 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- MYOM2 | c.3404A>C p.Y1135S | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- NET1 | c.283C>G p.L95V (on ENST00000355029 / NM_001047160.3; = p.L41V on NM_005863.5) | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.241); called by muse, mutect2
- NLRC5 | c.4728G>T p.Q1576H | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NOP53 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NUF2 | c.198G>T p.M66I | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NXPH3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- OR10A7 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 71/470 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR13A1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- OR2J3 | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR51B6 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- OR5K4 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 27/448 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8A1 | c.751T>A p.Y251N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- OR9Q1 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OTOL1 | c.1057T>A p.F353I | Missense Mutation (SNP) | VAF 30/721 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PAK3 | c.795G>T p.E265D (on ENST00000262836 / NM_001324328.2; = p.E250D on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDH1 | c.2537G>T p.R846L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB5 | c.1193A>T p.N398I | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCOLCE2 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PDE3A | c.2566G>T p.A856S | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE4B | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); called by muse, varscan2
- PDZRN3 | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PHKA1 | c.1662G>A p.W554* | Nonsense Mutation (SNP) | VAF 75/187 reads (40%) | called by muse, mutect2, varscan2
- PHKG1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.043); called by muse, mutect2
- PLCL1 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PPFIBP1 | c.2158G>A p.D720N (on ENST00000318304 / NM_177444.3; = p.D714N on NM_003622.4) | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF8 | c.971T>A p.L324Q | Missense Mutation (SNP) | VAF 84/652 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PREX1 | c.1882-4C>A | Splice Region (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- PTGER3 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PTPRC | c.1376T>A p.L459* | Nonsense Mutation (SNP) | VAF 36/247 reads (15%) | called by muse, mutect2, varscan2
- PXK | c.1630G>C p.V544L | Missense Mutation (SNP) | VAF 80/391 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- RDH12 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RELN | c.7219T>G p.W2407G | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RFX2 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SBSN | c.623A>T p.Q208L | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- SCN1A | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC14L6 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SERPINA4 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SH2B2 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.039); called by muse, mutect2
- SH3PXD2A | c.2936C>A p.P979H (on ENST00000369774 / NM_001365079.1; = p.P951H on NM_014631.2) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SI | c.2833C>G p.P945A | Missense Mutation (SNP) | VAF 12/415 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC12A3 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SLC25A3 | c.920G>T p.G307V (on ENST00000228318 / NM_005888.3; = p.G306V on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/684 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK1 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.344); called by muse, mutect2
- SNTG1 | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPAG17 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSH1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- STAB2 | c.6484C>A p.L2162M | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SYNE1 | c.18407A>C p.K6136T (on ENST00000367255 / NM_182961.4; = p.K6065T on NM_033071.3) | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TAS2R9 | c.178T>A p.C60S | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TCTN2 | c.1984+4G>A | Splice Region (SNP) | VAF 52/317 reads (16%) | called by muse, mutect2, varscan2
- TDRD15 | c.2438G>T p.G813V | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TDRD15 | c.3290G>T p.W1097L | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TICRR | c.4076C>A p.S1359* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- TLN2 | c.2722G>T p.A908S | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); called by muse, mutect2
- TMEM88 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- TNRC6C | c.4572+8A>G | Splice Region (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- TNS2 | c.784C>G p.L262V (on ENST00000314250 / NM_170754.4; = p.L272V on NM_015319.2) | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- TPO | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TRPV2 | c.468C>A p.C156* | Nonsense Mutation (SNP) | VAF 54/321 reads (17%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.2261G>T p.S754I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- TTLL2 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- UTP25 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2
- UTP4 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 69/436 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UTRN | c.4130C>T p.A1377V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- VPS54 | c.2467G>T p.V823L | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR64 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, varscan2
- WNK3 | c.4483C>G p.Q1495E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- WT1 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- XRCC5 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- YEATS2 | c.466A>G p.N156D | Missense Mutation (SNP) | VAF 36/467 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ZBBX | c.719G>C p.R240P | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED6 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZBTB39 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZFHX3 | c.1713C>G p.S571R | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ZNF189 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ZNF257 | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ZNF462 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); called by muse, mutect2
- ZNF462 | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ZNF469 | c.5729C>T p.S1910L (on ENST00000437464; = p.S1938L on NM_001367624.2) | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ZNF516 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF569 | c.1688C>G p.S563* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- ZNF578 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZNF667 | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF730 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2
- ZNF8 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF835 | c.1002C>G p.Y334* | Nonsense Mutation (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- ADARB1 | c.588G>T p.G196= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV62346938; called by muse, mutect2
- ADGRA1 | c.1170G>A p.L390= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- ADGRD2 | c.2205C>T p.L735= | Silent (SNP) | VAF 17/192 reads (9%) | catalogued as COSV58342738; called by muse, mutect2
- AGRN | c.4347A>G p.V1449= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- AHNAK2 | c.14622C>A p.V4874= | Silent (SNP) | VAF 78/201 reads (39%) | called by muse, mutect2, varscan2
- AMY2B | c.1248G>C p.V416= | Silent (SNP) | VAF 41/392 reads (10%) | called by muse, mutect2, varscan2
- ARHGEF33 | c.2220C>A p.A740= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- CD163 | c.162G>T p.V54= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2
- CDH9 | c.411G>T p.R137= | Silent (SNP) | VAF 52/481 reads (11%) | catalogued as rs1292467358, COSV99141761; called by muse, mutect2, varscan2
- CNGA4 | c.399C>A p.G133= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV101171832; called by muse, mutect2, varscan2
- CPN1 | c.99G>A p.R33= | Silent (SNP) | VAF 23/370 reads (6%) | catalogued as rs1374090037; called by muse, mutect2
- CTNND2 | c.2104C>A p.R702= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV58868050, COSV58920204; called by muse, mutect2, varscan2
- CYFIP2 | c.1944A>T p.R648= (on ENST00000616178 / NM_001291722.2; = p.R623= on NM_014376.4) | Silent (SNP) | VAF 44/169 reads (26%) | called by muse, mutect2, varscan2
- DENND2B | c.183C>A p.S61= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- DNAH10 | c.1755C>T p.F585= (on ENST00000409039; = p.F524= on NM_207437.3) | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as rs1437227862; called by muse, mutect2
- DPP9 | c.1731G>C p.L577= (on ENST00000598800; = p.L606= on NM_139159.5) | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- EXTL1 | c.516C>T p.T172= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV65337400; called by muse, mutect2, varscan2
- FAM89B | c.81C>T p.L27= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- GAD2 | c.1395C>A p.T465= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV52165019, COSV99393726; called by muse, mutect2, varscan2
- GATA4 | c.588C>A p.A196= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV58734219; called by muse, mutect2, varscan2
- GC | c.1239T>C p.N413= | Silent (SNP) | VAF 58/218 reads (27%) | called by muse, mutect2, varscan2
- H1-8 | c.279C>T p.F93= | Silent (SNP) | VAF 28/200 reads (14%) | called by muse, mutect2, varscan2
- HOXD12 | c.498C>T p.T166= | Silent (SNP) | VAF 28/219 reads (13%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.159C>A p.I53= | Silent (SNP) | VAF 143/427 reads (33%) | called by muse, mutect2, varscan2
- ITGA8 | c.2175G>T p.V725= | Silent (SNP) | VAF 43/407 reads (11%) | called by muse, mutect2, varscan2
- KCNH7 | c.3525C>A p.S1175= | Silent (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- LAMA2 | c.846A>T p.S282= | Silent (SNP) | VAF 85/363 reads (23%) | called by muse, mutect2, varscan2
- LAMA2 | c.2736G>T p.A912= | Silent (SNP) | VAF 76/380 reads (20%) | catalogued as COSV70355651; called by muse, mutect2, varscan2
- MEP1B | c.1122G>T p.V374= | Silent (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2
- MYH15 | c.3901C>A p.R1301= | Silent (SNP) | VAF 36/177 reads (20%) | called by muse, mutect2
- MYH2 | c.5407C>T p.L1803= | Silent (SNP) | VAF 25/593 reads (4%) | catalogued as rs371411603; called by muse, mutect2
- MYO9A | c.4641C>G p.S1547= | Silent (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- NPAP1 | c.2763C>T p.T921= | Silent (SNP) | VAF 35/196 reads (18%) | called by muse, mutect2, varscan2
- NRN1L | c.402G>A p.T134= | Silent (SNP) | VAF 18/245 reads (7%) | catalogued as rs779900445; called by muse, mutect2
- OR10K1 | c.57C>G p.S19= | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- OXCT1 | c.501A>G p.E167= | Silent (SNP) | VAF 57/388 reads (15%) | called by muse, mutect2, varscan2
- PCDH9 | c.3297G>T p.P1099= (on ENST00000377865 / NM_203487.3; = p.P1065= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV60554876; called by muse, mutect2, varscan2
- PCDHB11 | c.213G>A p.K71= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as COSV53382146; called by muse, mutect2, varscan2
- PLPPR4 | c.1722C>A p.P574= | Silent (SNP) | VAF 48/268 reads (18%) | catalogued as COSV64567823; called by muse, mutect2, varscan2
- PLXNA2 | c.4650C>T p.D1550= | Silent (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- PRR23A | c.150T>C p.G50= | Silent (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- PSG6 | c.663A>G p.P221= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- RBM47 | c.1371A>C p.P457= (on ENST00000295971 / NM_001098634.2; = p.P388= on NM_019027.4) | Silent (SNP) | VAF 45/213 reads (21%) | called by muse, mutect2, varscan2
- RNMT | c.573A>G p.V191= | Silent (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- SAP130 | c.1656A>C p.A552= | Silent (SNP) | VAF 52/318 reads (16%) | called by muse, mutect2, varscan2
- SPART | c.657T>C p.D219= | Silent (SNP) | VAF 22/424 reads (5%) | called by muse, mutect2
- ST14 | c.2388C>G p.G796= | Silent (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- SYCP3 | c.300C>G p.L100= | Silent (SNP) | VAF 26/350 reads (7%) | called by muse, mutect2
- TDRD15 | c.2439G>T p.G813= | Silent (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- TOP2B | c.912G>A p.G304= (on ENST00000264331 / NM_001330700.2; = p.G299= on NM_001068.3) | Silent (SNP) | VAF 34/234 reads (15%) | called by muse, varscan2
- TRRAP | c.6600C>T p.C2200= (on ENST00000359863 / NM_001244580.1; = p.C2182= on NM_003496.3) | Silent (SNP) | VAF 15/381 reads (4%) | called by muse, mutect2
- ZNF385D | c.339C>A p.A113= | Silent (SNP) | VAF 28/217 reads (13%) | catalogued as COSV99872857; called by muse, mutect2, varscan2
- ZNF416 | c.1536C>T p.H512= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV52183418; called by muse, mutect2, varscan2
- ZNF705A | c.93G>A p.L31= | Silent (SNP) | VAF 42/856 reads (5%) | called by muse, mutect2
- ZNF730 | c.186T>G p.P62= | Silent (SNP) | VAF 30/328 reads (9%) | catalogued as COSV74168455; called by muse, mutect2
- AC090155.1 | n.171C>A | RNA (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- AMPH | c.1182+347G>A | Intron (SNP) | VAF 53/229 reads (23%) | called by muse, mutect2, varscan2
- ATP1A3 | c.3052+38G>T | Intron (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- ATP6AP1 | c.924-18C>G | Intron (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- BSCL2 | chr11:62707308 T>C | 5'Flank (SNP) | VAF 53/343 reads (15%) | called by muse, mutect2, varscan2
- C2orf91 | n.317C>G | RNA (SNP) | VAF 39/328 reads (12%) | called by muse, mutect2, varscan2
- CADM2 | c.-6G>A | 5'UTR (SNP) | VAF 38/180 reads (21%) | catalogued as rs1310758976; called by muse, mutect2, varscan2
- CCDC107 | chr9:35657784 G>C | 5'Flank (SNP) | VAF 6/30 reads (20%) | catalogued as rs1002409010; called by muse, varscan2
- CEACAM5 | c.703+74C>A | Intron (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- CELF2 | c.1076-2314C>T | Intron (SNP) | VAF 24/344 reads (7%) | called by muse, mutect2
- CHODL | c.-63G>T | 5'UTR (SNP) | VAF 8/120 reads (7%) | catalogued as rs1023401349; called by muse, mutect2
- CTBP2 | c.58+12770C>T | Intron (SNP) | VAF 16/108 reads (15%) | catalogued as rs1331954974; called by muse, mutect2, varscan2
- DPPA4 | c.679+124C>A | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- DUOXA2 | c.555-15C>T | Intron (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- FAM86C2P | n.1058G>C | RNA (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- FNTA | c.783-49C>G | Intron (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- GRB10 | c.1195-31C>A | Intron (SNP) | VAF 51/277 reads (18%) | called by muse, mutect2, varscan2
- GRID1 | c.236-58052A>T | Intron (SNP) | VAF 25/222 reads (11%) | called by muse, mutect2, varscan2
- H2BC18 | c.378-9404C>A | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- HMGA2 | c.250-36286A>C | Intron (SNP) | VAF 23/534 reads (4%) | called by muse, mutect2
- HSPB6 | c.-12C>A | 5'UTR (SNP) | VAF 34/156 reads (22%) | catalogued as rs769686035; called by muse, mutect2, varscan2
- IDH3B | c.*15dup | 3'UTR (INS) | VAF 25/234 reads (11%) | called by mutect2, pindel, varscan2
- KCNE2 | c.*43G>A | 3'UTR (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- LPIN1 | c.-8G>A | 5'UTR (SNP) | VAF 16/151 reads (11%) | catalogued as COSV70686007; called by muse, mutect2
- LRRC37A | c.2906+4888C>A | Intron (SNP) | VAF 35/311 reads (11%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.1646C>T | RNA (SNP) | VAF 16/261 reads (6%) | called by muse, mutect2
- MARCHF8 | c.242+448A>G | Intron (SNP) | VAF 25/152 reads (16%) | called by muse, mutect2, varscan2
- MT3 | chr16:56589158 G>T | 5'Flank (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- ODF3B | c.540+30G>T | Intron (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- OXR1 | c.223+62108G>C | Intron (SNP) | VAF 22/368 reads (6%) | called by muse, mutect2
- PENK | chr8:56436968 C>A | 3'Flank (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- PITX2 | c.390+1011C>T | Intron (SNP) | VAF 37/153 reads (24%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*714C>G | 3'UTR (SNP) | VAF 7/28 reads (25%) | catalogued as rs981963908; called by muse, mutect2, varscan2
- PTGER3 | c.*24-12949T>C | Intron (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- PTPN9 | c.528+3948C>G | Intron (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- PWWP3A | c.1989+10G>T | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- RAP1GAP | c.-148-1997C>A | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- RN7SL759P | chr15:20572670 C>A | 3'Flank (SNP) | VAF 100/591 reads (17%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.449C>A | RNA (SNP) | VAF 56/546 reads (10%) | catalogued as rs892415671; called by muse, varscan2
- SETDB2 | chr13:49443996 A>T | 5'Flank (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-51578T>A | Intron (SNP) | VAF 28/200 reads (14%) | called by muse, mutect2, varscan2
- TMEM107 | c.*734A>G | 3'UTR (SNP) | VAF 28/105 reads (27%) | catalogued as rs758890705; called by muse, mutect2
- TMEM196 | c.*51T>C | 3'UTR (SNP) | VAF 49/265 reads (18%) | catalogued as COSV68254981; called by muse, mutect2, varscan2
- TMEM273 | c.238+69C>G | Intron (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2
- TPP1 | c.509-67G>T | Intron (SNP) | VAF 7/49 reads (14%) | catalogued as rs762702090; called by muse, mutect2, varscan2
- WDR92 | c.-42G>T | 5'UTR (SNP) | VAF 30/163 reads (18%) | catalogued as rs1446998877; called by muse, mutect2, varscan2
- WT1 | chr11:32439258 C>A | 5'Flank (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- ZNF99 | c.*50T>C | 3'UTR (SNP) | VAF 40/352 reads (11%) | catalogued as rs375870113; called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836537 G>A | 3'Flank (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
